Somatic mutation profile of tumor specimen TCGA-DU-6542-01A (aliquot TCGA-DU-6542-01A-11D-1893-08) from TCGA case TCGA-DU-6542, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 25.7 years (9,380 days).
Specimen TCGA-DU-6542-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1374729-a30d-41a1-84e8-137cd1ad942f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-6542-10A (Blood Derived Normal), aliquot TCGA-DU-6542-10A-01D-1893-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a24078f-f635-43e6-b446-7e9e89f02f82

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 16, Silent 7, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 20/69 reads (29%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 28/33 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AP002512.3 | c.347C>G p.T116S | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV54406270; called by muse, mutect2, varscan2
- APPBP2 | c.465G>C p.E155D | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.585); catalogued as rs750398565, COSV50026429; called by muse, mutect2, varscan2
- CCDC173 | c.143C>G p.T48S | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as COSV69572467, COSV69572787; called by muse, mutect2, varscan2
- CELSR3 | c.4357C>T p.R1453C | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs756629829, COSV50848916; called by muse, mutect2, varscan2
- CFAP44 | c.2164T>C p.F722L | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV55610595; called by muse, mutect2, varscan2
- CLCN6 | c.499_502del p.N167Afs*2 | Frame Shift Del (DEL) | VAF 30/100 reads (30%) | catalogued as rs749793446; called by mutect2, pindel, varscan2
- DDX43 | c.1144A>G p.S382G | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV64836753; called by muse, mutect2, varscan2
- OR4X1 | c.312C>A p.F104L | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV60722222, COSV60722666; called by muse, mutect2, varscan2
- P2RY6 | c.176C>T p.T59I | Missense Mutation (SNP) | VAF 56/253 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV62936295; called by muse, mutect2, varscan2
- PATJ | c.4892G>A p.G1631D | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.096); catalogued as rs776193374, COSV100957497, COSV64502870; called by muse, mutect2, varscan2
- PLA2G2D | c.290G>A p.C97Y | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64281579; called by muse, mutect2, varscan2
- SELP | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55250819; called by muse, mutect2
- TRIM48 | c.556-2A>G p.X186_splice | Splice Site (SNP) | VAF 34/92 reads (37%) | catalogued as COSV70161024; called by muse, mutect2
- TTN | c.82480C>G p.L27494V (on ENST00000591111; = p.L20070V on NM_003319.4) | Missense Mutation (SNP) | VAF 21/281 reads (7%) | PolyPhen probably damaging (0.996); catalogued as COSV59995331, COSV59995906; called by muse, mutect2
- ZAN | c.5441C>T p.P1814L | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV61807951; called by muse, mutect2, varscan2
- ZNF605 | c.750G>C p.E250D | Missense Mutation (SNP) | VAF 113/149 reads (76%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ABCC3 | c.153C>T p.C51= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV53320245, COSV53327623; called by muse, mutect2, varscan2
- ABCF2 | c.1791C>T p.D597= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV55181439; called by muse, mutect2, varscan2
- HMCN1 | c.8298A>T p.P2766= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV54893338; called by muse, mutect2, varscan2
- PTPRD | c.4449G>A p.T1483= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as rs1439440841, COSV61938973; called by muse, mutect2, varscan2
- TNN | c.255C>A p.I85= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as COSV53424880; called by muse, mutect2, varscan2
- TRPV5 | c.1725C>T p.I575= | Silent (SNP) | VAF 16/127 reads (13%) | catalogued as rs766468509, COSV54684871; called by muse, mutect2, varscan2
- UGT1A6 | c.696C>T p.L232= | Silent (SNP) | VAF 14/190 reads (7%) | catalogued as rs536034017, COSV59386965; called by muse, mutect2
